Somatic mutation profile of tumor specimen TCGA-AR-A0TP-01A (aliquot TCGA-AR-A0TP-01A-11D-A099-09) from TCGA case TCGA-AR-A0TP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 43.3 years (15,812 days).
Specimen TCGA-AR-A0TP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5ba931b-f743-44d9-9506-c833d7d8a77f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TP-10A (Blood Derived Normal), aliquot TCGA-AR-A0TP-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f04cf6-d2ae-43f7-9830-78235164fccf

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 13, Frame Shift Del 4, In Frame Del 1, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 72/90 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOF | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100029115; called by muse, mutect2, varscan2
- C9orf43 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99928559; called by muse, mutect2, varscan2
- CCNA1 | c.1220C>A p.T407N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV99714852; called by muse, mutect2, varscan2
- CCNB1IP1 | c.393C>G p.S131R | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV100738646; called by muse, mutect2, varscan2
- COL6A2 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as CM1010427, COSV100154152, COSV56008443; called by muse, mutect2, varscan2
- CYP4F8 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV100358219, COSV57854251; called by muse, mutect2, varscan2
- DTWD2 | c.870A>T p.E290D | Missense Mutation (SNP) | VAF 174/188 reads (93%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100407141; called by muse, mutect2, varscan2
- EIF4G2 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101151102; called by muse, mutect2
- ELN | c.1432G>C p.G478R | Missense Mutation (SNP) | VAF 212/450 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV52706931; called by muse, mutect2, varscan2
- FBXO10 | c.2839A>C p.S947R | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99447214; called by muse, mutect2, varscan2
- HECTD1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 144/167 reads (86%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV101237499; called by muse, mutect2, varscan2
- HMGN5 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 414/518 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1039831497, COSV63916915; called by muse, mutect2, varscan2
- IL23R | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 105/110 reads (95%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as rs1171424420, COSV100724906; called by muse, mutect2, varscan2
- IRS4 | c.2750G>T p.S917I | Missense Mutation (SNP) | VAF 127/257 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV64534863; called by muse, mutect2, varscan2
- KCNA6 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV54976433, COSV99768934; called by muse, mutect2, varscan2
- LIF | c.102T>G p.C34W | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99969981; called by muse, mutect2, varscan2
- LRRC24 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV99468149; called by muse, varscan2
- MAN2A1 | c.3373A>G p.N1125D | Missense Mutation (SNP) | VAF 68/86 reads (79%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV99811815; called by muse, mutect2, varscan2
- MS4A14 | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 121/257 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV100279744; called by muse, mutect2, varscan2
- MSMO1 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 83/88 reads (94%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV99823412; called by muse, mutect2, varscan2
- MUC16 | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.096); catalogued as COSV101201362; called by muse, mutect2, varscan2
- NEXMIF | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 133/148 reads (90%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99281694; called by muse, mutect2, varscan2
- NME9 | c.742G>A p.V248I (on ENST00000333911 / NM_001349024.2; = p.V187I on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs763521362, COSV58616800; called by muse, mutect2, varscan2
- PCNT | c.2402A>G p.D801G | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100855995; called by muse, mutect2, varscan2
- PDE3A | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV62974473; called by muse, mutect2, varscan2
- PDS5A | c.2771A>C p.E924A | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV100337539; called by muse, mutect2, varscan2
- PRKAR2B | c.647A>G p.D216G | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99708614; called by muse, mutect2, varscan2
- RDH5 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141868; called by muse, mutect2, varscan2
- RIMS3 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV101013560; called by muse, mutect2, varscan2
- ROS1 | c.6797C>G p.T2266R | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV100877654, COSV63857208; called by muse, mutect2, varscan2
- S100A10 | c.104T>G p.M35R | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100916739; called by muse, mutect2, varscan2
- SALL1 | c.2487G>A p.M829I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV99180121; called by muse, mutect2, varscan2
- SCN2A | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs747086776, COSV51837111, COSV51854657; called by muse, mutect2, varscan2
- SEC24D | c.1163G>C p.C388S | Missense Mutation (SNP) | VAF 69/82 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99756719; called by muse, mutect2, varscan2
- SMPDL3A | c.916A>G p.K306E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100868731; called by muse, mutect2
- TBC1D19 | c.870G>T p.L290F | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99336754; called by muse, mutect2, varscan2
- TFAP2B | c.585G>C p.Q195H | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs1254691372, COSV99540759; called by muse, mutect2, varscan2
- TNS3 | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100236286; called by muse, mutect2, varscan2
- WDR44 | c.2378G>A p.S793N | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99561901; called by muse, mutect2, varscan2
- ZFHX4 | c.8701A>G p.T2901A | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99266862; called by muse, mutect2, varscan2
- ZNF577 | c.163A>G p.N55D | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100031252; called by muse, mutect2, varscan2
- ABCC9 | c.1992dup p.A665Rfs*57 | Frame Shift Ins (INS) | VAF 86/214 reads (40%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.2505del p.A836Lfs*19 (on ENST00000506720 / NM_001322402.2; = p.A768Lfs*19 on NM_015236.6) | Frame Shift Del (DEL) | VAF 85/134 reads (63%) | called by mutect2, pindel, varscan2
- ATP2C1 | c.1461del p.K488Sfs*13 | Frame Shift Del (DEL) | VAF 86/319 reads (27%) | called by mutect2, pindel, varscan2
- LMTK3 | c.795-1_811del p.X265_splice | Splice Site (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- NEK11 | c.1444_1452del p.A482_D484del | In Frame Del (DEL) | VAF 44/192 reads (23%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.1751_1769del p.L584Pfs*76 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- SEMA3D | c.961del p.Y321Tfs*20 | Frame Shift Del (DEL) | VAF 81/209 reads (39%) | called by mutect2, pindel, varscan2
- ABCA3 | c.3774G>T p.G1258= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100069064, COSV100069198; called by muse, mutect2, varscan2
- ARHGEF10L | c.2643G>A p.P881= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs764649441, COSV99393725; called by muse, mutect2
- BEND4 | c.1467C>T p.D489= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs767568135, COSV101549795; called by muse, mutect2, varscan2
- E4F1 | c.24G>A p.R8= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- H2AC20 | c.291G>A p.L97= | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as COSV100480148; called by muse, mutect2, varscan2
- HRNR | c.8052T>C p.Y2684= | Silent (SNP) | VAF 66/126 reads (52%) | catalogued as COSV100913883; called by muse, mutect2, varscan2
- KLHL3 | c.1203C>G p.G401= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs1225499505, COSV100553515, COSV59054661; called by muse, mutect2, varscan2
- LAMA1 | c.6120T>C p.S2040= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV101057556; called by muse, mutect2, varscan2
- LCK | c.879G>A p.K293= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100288080; called by muse, mutect2, varscan2
- PKHD1 | c.10065G>A p.K3355= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs769691238, COSV100584404; called by muse, mutect2, varscan2
- PKHD1L1 | c.6822T>C p.P2274= | Silent (SNP) | VAF 57/216 reads (26%) | catalogued as COSV101006750; called by muse, mutect2, varscan2
- SCAF1 | c.3483C>G p.P1161= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100567020; called by muse, mutect2, varscan2
- ZNF506 | c.1038T>C p.C346= | Silent (SNP) | VAF 82/159 reads (52%) | catalogued as COSV101475661; called by muse, mutect2, varscan2
- GPHN | c.729+1324C>T | Intron (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100017555; called by muse, mutect2, varscan2
